Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A22Y, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A22Y-01A (Primary Tumor).

[page 1 of 5]
1CB-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: endometrium C54.1 w 4/21/11

Surgical Pathology Consultation Report

Gender: F

Specimen(s) Received

1. Lymph node: Right iliac external node
2. Lymph node: Right internal iliac node
3. Lymph node: Right Obturator lymph node
4. Lymph node: Left external iliac lymph node
5. Lymph node: Left internal iliac lymph node
6. Lymph node: Left obturator lymph node
7. Uterus: Uterus tubes and ovaries

Diagnosis

1. Lymph nodes, right external iliac:
- Nine lymph nodes, all negative for carcinoma (0/9)
2. Lymph nodes, right internal iliac:
- Seven lymph nodes, all negative for carcinoma (0/7)
3. Lymph nodes, right obturator:
- Three lymph nodes, all negative for carcinoma (0/3)
4. Lymph nodes, left external iliac:
- Nine lymph nodes, all negative for carcinoma (0/9)
5. Lymph node, left internal iliac:
- One lymph node, negative for carcinoma (0/1)
6. Lymph nodes, left obturator:
- Four lymph nodes, all negative for carcinoma (0/4)
7. Uterus, cervix, bilateral ovaries and fallopian tubes, Total abdominal hysterectomy and bilateral salpingo-oophorectomy:
- Endometrium:
- ENDOMETRIAL ENDOMETRIOID ADENOCARCINOMA WITH SQUAMOUS DIFFERENTIATION, FIGO GRADE 3/3**

rx/PA Discrepancy		X
Death Synchronous Primary Noted		X

[page 2 of 5]
- Background of complex hyperplasia with atypia.

Myometrium:

- Invaded by endometrial carcinoma, limited to inner half.
- Leiomyomata.

Cervix:

- Endocervical gland involvement by endometrial adenocarcinoma

Uterine serosa:

- Negative for carcinoma

Right & left ovaries:

- Epithelial inclusion cysts.

Right Fallopian tube:

- No histological abnormality.

Left Fallopian tube:

- Paratubal cyst.

Synoptic Data

----- MACROSCOPIC -----

Specimen Type:	Total Hysterectomy
Tumor Site:	Fundus
Tumor Size:	Greatest dimension: 4.8 cm Additional dimensions: 4.2 x 0.8 cm
Other Organs Present:	Right ovary Left ovary Right fallopian tube Left fallopian tube Lymph nodes

----- MICROSCOPIC -----

Histologic Type:	Endometrioid adenocarcinoma, with squamous differentiation
Histologic Grade:	G3: More than 50% nonsquamous solid growth
Myometrial Invasion:	Invasion Present Less than 50% myometrial invasion
Cervix Involvement:	Glandular involvement of endocervix
LUS Involvement:	Yes
Venous/Lymphatic Invasion:	Present
Nodal Involvement:	None
Margins:	Uninvolved by invasive carcinoma
Primary Tumor (pT):	Tumor limited to the glandular epithelium of the endocervix. There is no evidence of connective tissue stromal invasion.
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 33 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	pMX: Distant metastasis cannot be assessed
Additional Pathologic Findings:	Hyperplasia Atypical hyperplasia-Complex (adenomatous)
Neoadjuvant Treatment:	No
Collaborative Staging Extension:	Cannot be assessed

[page 3 of 5]
verified by:

Gross Description

1. The specimen container is labeled with the patient's name and as "uterus hysterectomy BSO" contains a uterus, cervix, bilateral fimbriated fallopian tube and bilateral ovaries received in 10% buffered formalin. The uterus measures 11.5 SI x 8.5 ML x 6.5 cm AP and the cervix measures 2.9 cm. in diameter with a 0.8 cm slit like os. The right and left fimbriated fallopian tube measures 3.0 x 0.4 cm and 5.0 x 0.4 cm respectively. The right and left ovary measures 3.0 x 1.5 x 0.9 cm and 2.4 x 1.8 x 1.0 cm respectively. The entire specimen weighs 365.3 g. On gross examination, the external surface of the right and a fimbriated fallopian tube is brown-tan in color, and has presence of small paratubal cysts ranging in size from 0.2 x 0.2 x 0.2 to 0.3 x 0.3 x 0.3 cm filled clear fluid. The external surface of the right and left ovary is tan in color, smooth and grossly unremarkable. On sectioning, the cut surface is tan in color, solid and firm except for a small cystic lesion identified on the cut surface of the left ovary measuring 0.8 x 0.4 x 0.4 cm filled with clear fluid. Most of the anterior and posterior uterine serosa is tan in color, smooth and grossly unremarkable except for a large well-circumscribed nodule present on the anterior uterine serosa measuring 4.5 x 4.3 x 3.9 cm. The cut surface of the nodule is white-tan in color, solid, firm and has a whorled appearance. On sectioning, a polypoid tumor is identified on the anterior and posterior endometrium measuring 3.9 SI x 6.5 ML x 3.8 cm AP. The cut surface of the tumor is white-tan in color, centrally soft and friable with the peripheral aspect firm and solid. Focal areas of hemorrhages are also noted. The tumor appears to invade through the myometrium with the myometrium measuring 0.6 cm in thickness. The rest of the myometrium has a trabeculated appearance. Multiple well-circumscribed nodules are also identified on both the anterior and posterior myometrium ranging in size from 1.6 x 1.5 x 1.8 cm to 2.8 x 2.5 x 2.2 cm. The cut surface of the nodule is white-tan in color, solid and firm with a whorled appearance. Both the anterior and posterior endocervix is tan in color and grossly unremarkable. Multiple pinpoint hemorrhages are noted on both the anterior and posterior exocervix.

Representative sections are submitted as follows:

- 1A left ovary and fallopian tube sections taken by research assistant
- 1B right ovary and fallopian tube sections taken by research assistant
- 1C representative section endometrial tumor sections taken by research assistant
- 1D the rest of the right fallopian tube serially sectioned and submitted in toto
- 1E-1G the rest of the right ovary serially sectioned and submitted in toto
- 1H-1I the rest of the left fallopian tube serially sectioned and submitted in toto
- 1J-1K the rest of the left ovary serially sectioned and submitted in toto
- 1L-1P anterior endomyometrium superior aspect full-thickness
- 1Q-1U anterior endomyometrium mid aspect to cervix longitudinal section
- 1V - 1AA posterior endomyometrium superior aspect full thickness (each slice bisected)
- 1AB1AD posterior endomyometrium mid inferior aspect to cervix longitudinal section

2. The specimen container labeled with the patient's name and as "right external iliac lymph node" contains a multiple pieces of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 1.5 x 1.0 x 0.8 to 3.5 x 2.8 x 1.3 cm. Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.3 x 0.2 x 0.2 to 1.5 x 1.1 x 1.0 cm. The specimen is submitted in toto as follows:

- 2A one lymph node bisected
- 2B two lymph nodes
- 2C one lymph node bisected
- 2D one lymph node bisected

[page 4 of 5]
2E one lymph node bisected
2F -2H the rest of the fatty tissue submitted in toto

3. The specimen container labelled with the patient's name and as "right internal iliac lymph node" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 2.5 x 0.6 x 0.5 cm. Within the fatty tissue, one lymph node is identified measuring 0.8 x 0.4 x 0.4 cm. The specimen is submitted in toto as follows:

3A one lymph node
3B the rest of the fatty tissue submitted in toto

4. The specimen container labelled with the patient's name and as "right obturator lymph node" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 3.5 x 2.8 x 1.8 cm. Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.3 x 0.3 x 0.3 to 2.5 x 1.5 x 1.0 cm The specimen is submitted in toto as follows:

4A one lymph node bisected
4B two lymph nodes
4C the rest of the fatty tissue submitted in toto

5. The specimen container labeled with the patient's name and as "right common iliac lymph node" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 2.5 x 0.8 x 0.6 cm. Within the fatty tissue, two lymph nodes are identified measuring 1.1 x 0.6 x 0.4 and 1.1 x 0.8 x 0.5 cm The specimen is submitted in toto as follows:

5A one lymph node bisected
5B one lymph node bisected with the rest of the fatty tissue submitted in toto

6. The specimen container labeled with the patient's name and as "right lower paraortic lymph node" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 2.3 x 1.5 x 0.7 cm. Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.2 x 0.2 x 0.2 cm to 0.6 x 0.5 x 0.4 cm The specimen is submitted in toto as follows:

6A one lymph node bisected with surrounding fatty tissue submitted in toto
6B one lymph node bisected with surrounding fatty tissue submitted in toto
6C two lymph nodes

7. The specimen container labeled with the patient's name and as "left external iliac lymph node" contains two pieces of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 1.5 x 1.0 x 0.8 to 3.5 x 2.8 x 1.3 cm. Within the fatty tissue, two lymph nodes are identified grossly measuring 0.6 x 0.6 x 0.5 and 3.1 x 1.5 x 1.0 cm The specimen is submitted in toto as follows:

7A 7B one lymph node bisected
7C one lymph node bisected
7D 7E the rest of the fatty tissue submitted in toto

8. The specimen container labeled with the patient's name and as "left internal iliac lymph node" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 3.3 x 1.5 x 1.3 cm. Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.5 x 0.5 x 0.4 to 2.1 x 0.6 x 0.7 cm. The specimen is submitted in toto as follows:

8A one lymph node
8B two lymph nodes
8C the rest of the fatty tissue submitted in toto

[page 5 of 5]
9. The specimen container labeled with the patient's name and as "left obturator lymph nodes" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 4.8 x 3.5 x 1.3 cm. Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.6 x 0.4 x 0.4 to 3.5 x 1.6 x 0.9 cm. The specimen is submitted in toto as follows:

9A one lymph node bisected

9B one lymph node bisected

9C- 9F one lymph node bisected (9C- 9D one half of lymph node bisected, 9E 9F other half of lymph node bisected)

9G the rest of the fatty tissue submitted in toto

10. The specimen container labeled with the patient's name and as "left common iliac lymph node" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 2.5 x 1.5 x 0.9 cm. Within the fatty tissue, two lymph nodes identified grossly measuring 0.5 x 0.4 x 0.3 to 0.6 x 0.6 x 0.4 cm. The specimen is submitted in toto as follows:

10A one lymph node bisected

10B one lymph node

10C the rest of the fatty tissue submitted in toto

11. The specimen container labeled with the patient's name and as "lower paraortic left" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 2.0 x 1.5 x 0.8 cm. Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.2 x 0.2 x 0.2 to 0.9 x 0.6 x 0.5 cm. The specimen is submitted in toto as follows:

11A multiple lymph nodes

11B one lymph node bisected

11C the rest of the fatty tissue submitted in toto

Source: NCI Genomic Data Commons file be589091-0581-4252-849e-049a562c9fb2 (TCGA-EO-A22Y.44F2A17C-265B-4C2A-9AA0-42C55A23B592.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).